Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7245, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7245-01A (Primary Tumor).

[page 1 of 4]
Collected

Received

cc:

Accession

Case type: Surgical Case

***** **MODIFIED REPORT - REVIEW ADDENDUM SECTION** *****

DIAGNOSIS

(A) LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, INVOLVING LEFT FALSE VOCAL CORDS, LEFT PYRIFORM SINUS, LEFT EPIGLOTTIS, AND EXTENDING TO LEFT ARYEPIGLOTTIC FOLD

Tumor Features:

Gross: Exophytic

Size: 5.5 cm in largest dimension

Invasion: Present, depth 2.0 cm

Tumor Border: Pushing

Perineural Invasion: Absent

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending decalcification

Lymphocyte Infiltration: Absent

Mucosal Margin: (en-face) Negative for invasive carcinoma

Deep Margin: Negative for invasive carcinoma

Dysplasia at Margin: Present, Mild dysplasia at Tracheal margin(s).

Tracheostomy, no tumor present

Thyroid gland, no tumor present

Hypercellular parathyroid

Three paratracheal lymph nodes, no tumor present.

Right neck dissection

No tumor present in 14 Lymph Nodes.

Level II:

Positive Nodes = 0

Total Nodes = 8

Level III:

Positive Nodes = 0

Total Nodes = 5

Level IV:

Positive Nodes = 0

Total Nodes = 1

Left neck dissection

No tumor present in 25 Lymph Nodes.

[page 2 of 4]
Level II:

Positive Nodes = 0

Total Nodes = 9

Level III:

Positive Nodes = 0

Total Nodes = 7

Level IV:

Positive Nodes = 0

Total Nodes = 9

(B) RIGHT PARATRACHEAL LYMPH NODE

Seven lymph nodes, no tumor present (0/7)

(C) TEETH

Five teeth, for gross identification only

GROSS DESCRIPTION

(A) LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION, CHECK MUCOSAL MARGIN ON THE PHARYNX AND TRACHEA - A total laryngectomy specimen, including larynx (12.0 x 6.0 x 5.0 cm) and bilateral attached neck dissections (12.0 x 4.0 x 2.5 cm). There is a pink-tan, exophytic tumor (5.5 x 3.0 x 2.5 cm) involving the left false vocal cords that extends superiorly to involve the left aryepiglottic fold, the left pyriform sinus, and left epiglottis. The true vocal cords are uninvolved. Posteriorly, the tumor appears to extend submucosally to the overlying hypopharyngeal mucosa. The tumor measures 2.0 cm from the closest left inferior posterior pharyngeal mucosal margin and 6.0 cm from the laryngeal margin. There is a tracheostomy site identified that is surrounded by a rim of tan-brown, partially wrinkled skin (6.0 x 3.0 x 2.0 cm) that is grossly uninvolved by tumor. The uninvolved laryngeal mucosa appears grossly unremarkable. A portion of possible thyroid tissue along the left neck is present (2.2 x 2.0 x 0.4 cm). Sections of tumor and normal laryngeal mucosa are taken for tissue bank, and the specimen is submitted to the bone lab.

SECTION CODE: A1, right posterior inferior pharyngeal mucosal margin, en face; A2, left posterior inferior pharyngeal mucosal margin, en face; A3, left lateral pharyngeal mucosal margin, en face; A4, right lateral pharyngeal mucosal margin, en face; A5, tracheal margin en face; A6, A7, representative sections of tumor; A8, tumor relative to left aryepiglottic fold; A9, tumor relative to left epiglottis; A10, tumor relative to overlying left pharyngeal mucosa; A11, uninvolved laryngeal mucosa; A12, superior tracheostomy skin, en face; A13, possible thyroid tissue; A14, A15, each five possible paratracheal lymph nodes; A16, four possible paratracheal lymph nodes; A17, seven possible left level II lymph nodes; A18-A22, each one bisected possible left level II lymph nodes; A23, six possible left level III lymph nodes; A24, one bisected possible left level III lymph node; A25, five possible left level IV lymph nodes; A26-A28, each one bisected possible left level IV lymph nodes.

A29-A31, level II lymph nodes, A29, one serially sectioned lymph node; A30, four possible lymph nodes; A31, five possible lymph nodes; A32-A34, level III lymph nodes, A32, one serially sectioned lymph node; A33, one bisected lymph node; A34, four possible lymph nodes; A35, level IV lymph node, one serially sectioned lymph node; A36, level IV lymph node, three possible lymph nodes; A37-A38, tumor in relation to the thyroid cartilage left side; A39, tumor in relation to the thyroid cartilage right side, will be submitted up to decal.

*FS/DX: NO TUMOR PRESENT.

[page 3 of 4]
(B) RIGHT PARATRACHEAL LYMPH NODE – Multiple fragments of fibrous tissue 2.5 x 2.5 x 1.0 cm. Eight lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 cm to 1.2 x 0.6 x 0.6 cm.

SECTION CODE: B1, three lymph nodes. B2, three lymph nodes; B3, two lymph nodes. [REDACTED]

(C) TEETH FOR GROSS ONLY - Five teeth measuring 2.5 x 2.5 x 1.0 cm in aggregate. The specimen submitted for gross only. [REDACTED]

CLINICAL HISTORY

Squamous cell carcinoma of larynx.

SNOMED CODES

T-C4200, M-80706, M-80703, M-Y4010, "Some tests reported here may have been developed and performance characteristics determined by Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration." [REDACTED]

Entire report and diagnosis completed by: [REDACTED]

Page 3 of 4	
Surgical Pathology Report	
File under: Pathology	

[page 4 of 4]
ADDENDUM

This modified report is being issued to add additional comments.

DIAGNOSIS

(A) LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION:
SQUAMOUS CARCINOMA EXTENDING INTO THYROID CARTILAGE.

Entire report and diagnosis completed by

Source: NCI Genomic Data Commons file 74092707-b87f-484f-b535-636d566cd341 (TCGA-CV-7245.0DD62255-EB26-492B-AC9B-DCC0EBEC4CD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).